Somatic mutation profile of tumor specimen TARGET-30-PANKFE-01A (aliquot TARGET-30-PANKFE-01A-01W) from TARGET case TARGET-30-PANKFE, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.5 years (1,280 days).
Specimen TARGET-30-PANKFE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c30ab52e-437e-4527-b5fe-28944e5466ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PANKFE-10A (Blood Derived Normal), aliquot TARGET-30-PANKFE-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a06c72b-f092-461f-adcd-f55ccc3cbbfd

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNA2 | c.2671C>T p.Q891* (on ENST00000402739 / NM_001282597.3; = p.Q843* on NM_004389.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 44/537 reads (8%) | called by muse, mutect2
- CYP11B2 | c.1307G>A p.R436K | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0.017); called by muse, mutect2
- ZBBX | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRM6 | c.1290C>T p.C430= | Silent (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- OVGP1 | c.1698G>A p.R566= | Silent (SNP) | VAF 44/1170 reads (4%) | catalogued as COSV63859536; called by muse, mutect2
